Gene-level copy-number profile of tumor specimen TCGA-XK-AAJ3-01A from TCGA case TCGA-XK-AAJ3, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.4 years (20,604 days).
Specimen TCGA-XK-AAJ3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.74e3c5da-e60a-4f14-8d4a-1c68561e23bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XK-AAJ3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/7b3edc5e-72c9-4feb-a3ec-7972b7b17df2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 98; copy number 1: 42; copy number 2: 5,203; copy number 3: 1,653; copy number 4: 50,028; copy number 5: 1; copy number 6: 2,794.

Homozygous deletions (total copy number 0; autosomes only): 98 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:97,504,663–103,562,790, 78 genes (broad region; genes not listed).
- chr5:104,079,847–105,392,970, 9 genes: LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P, AC091987.1, RAB9BP1.
- chr6:125,747,664–125,932,034, 4 genes: HEY2, NCOA7, NCOA7-AS1, RN7SKP56.
- chr13:65,309,855–65,310,953, 1 gene: STARP1.
- chr13:67,577,624–68,037,131, 6 genes: AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 42. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
